CGCI case HTMCP-02-03-01005 — HIV+ Tumor Molecular Characterization Project - Lung Cancer (CGCI-HTMCP-LC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/659cd411-54d4-4ccc-bd13-325ff9e80502

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 46 years; Vital status: Dead; Days to death: 94 days; Cause of death: Not Cancer Related.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 46.0 years (16,815 days); Year of diagnosis: 2009; Method of diagnosis: Surgical Resection; AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 74 days.
   Pathology details: Lymph nodes positive: 0; Lymph nodes tested: 14.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Progressive Disease.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Pharmaceutical Therapy, NOS; Pharmaceutical Therapy, NOS; Surgery, NOS.

Follow-up (4 entries)
- Days to follow up: 0 days; Karnofsky performance status: 80; ECOG performance status: 1.
- Days to follow up: 66 days; Disease response: With Tumor.
- Days to follow up: 74 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Lung, NOS; Days to recurrence: 74 days.
- Follow-up contact recording only the day: day -7,565.

Other clinical attributes
- Day -7,565: Risk factors: HIV/AIDS.
- Day -7,565: Comorbidities: HIV/AIDS.
- Day 0: CD4 count: 64; Haart treatment indicator: Yes; HIV viral load: 285.
- Day 0: Cdc hiv risk factors: Homosexual Contact.
- Day 0: AIDS risk factors: Pneumocystis Pneumonia.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 25; Tobacco smoking quit year: 2009.

Biospecimens (3 samples)
- Sample HTMCP-02-03-01005-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-02-03-01005-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-02-03-01005-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); Tumor status: With tumor; Tobacco smoking age started: 21; Cause of death: Non-Cancer Related; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tobacco smoking history indicator: 4; New tumor event diagnosis indicator: Yes.
- New tumor event: New tumor event site: Lung; New tumor event surgery: No; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: No.
- Anatomic neoplasm subdivision list: Anatomic organ subdivision: Upper lobe.
- History of disease: HIV status: Positive; Year of HIV diagnosis: 1989; Haart therapy at diagnosis: Yes; Haart therapy prior to diagnosis: Yes; Prior aids conditions: Pneumocystis jirovecii pneumonia; Cdc HIV risk group: Homosexual or bisexual contact.
- Primary pathology: Lymph nodes examined: Yes; Method initial path diagnosis: Tumor resection.
